Somatic mutation profile of tumor specimen C3L-05235-01 (aliquot CPT0346090006) from CPTAC case C3L-05235, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 57.7 years (21,061 days).
Specimen C3L-05235-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab54a460-c76d-4b31-b045-535dd9acedd5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05235-31 (Blood Derived Normal), aliquot CPT0346250002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20c54f2a-e756-41cf-9fc7-f15718c68d32

The open-access MAF lists 728 somatic variants for this specimen: 462 protein-altering or splice-affecting, 247 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 419, Silent 247, Nonsense Mutation 34, Intron 13, Splice Region 3, Frame Shift Del 2, 3'Flank 2, Splice Site 2, RNA 2, Translation Start Site 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 42/276 reads (15%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>G p.V640G (on ENST00000288602 / NM_001374244.1; = p.V600G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 396/534 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 391/529 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CACNA1A | c.5050C>T p.R1684C | Missense Mutation (SNP) | VAF 104/378 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121908243, CM101311; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 94/303 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 75/442 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV52628329; called by muse, mutect2, varscan2
- ABCA12 | c.1835C>T p.P612L (on ENST00000272895 / NM_173076.3; = p.P294L on NM_015657.3) | Missense Mutation (SNP) | VAF 116/392 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99790891; called by muse, mutect2, varscan2
- ABCB1 | c.1895G>A p.G632E | Missense Mutation (SNP) | VAF 113/279 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV55944664; called by muse, mutect2, varscan2
- ADAMDEC1 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 83/335 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.062); catalogued as rs767110341; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3427G>A p.E1143K | Missense Mutation (SNP) | VAF 102/466 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.107); catalogued as rs892864576, COSV54467237; called by muse, mutect2, varscan2
- ADGRF4 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 106/395 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as COSV51950162; called by muse, mutect2, varscan2
- AMPH | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs370790138; called by muse, mutect2, varscan2
- ANK3 | c.9181C>T p.P3061S | Missense Mutation (SNP) | VAF 111/436 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.992); catalogued as rs1299364308, COSV55044663; called by muse, mutect2, varscan2
- ANKRD45 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 63/261 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs372141282; called by muse, mutect2, varscan2
- ANKS1B | c.2735C>T p.S912L (on ENST00000547776 / NM_152788.4; = p.S138L on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/390 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60357807; called by muse, mutect2, varscan2
- ANO9 | c.1334G>A p.R445K | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); catalogued as COSV60449797; called by muse, mutect2, varscan2
- AQP7 | c.57G>A p.W19* | Nonsense Mutation (SNP) | VAF 92/342 reads (27%) | catalogued as rs1477831537; called by muse, mutect2, varscan2
- ARHGAP44 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 106/371 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as rs920998814; called by muse, mutect2, varscan2
- ARNT2 | c.1600G>A p.G534R | Missense Mutation (SNP) | VAF 80/306 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs745941675; called by muse, mutect2, varscan2
- ASTN1 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 140/513 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.35); catalogued as COSV99923111; called by muse, mutect2, varscan2
- B3GLCT | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs914062573, COSV58453355; called by muse, mutect2, varscan2
- BRPF3 | c.3200C>T p.P1067L | Missense Mutation (SNP) | VAF 92/441 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.217); catalogued as rs769524590, COSV60209333; called by muse, mutect2, varscan2
- C10orf71 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 108/389 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs745969517; called by muse, mutect2, varscan2
- C16orf54 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 150/522 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs774872519, COSV61477003; called by muse, mutect2, varscan2
- C1QTNF3 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 114/635 reads (18%) | catalogued as rs759158354, COSV51467791; called by muse, mutect2, varscan2
- CACNA2D4 | c.1613G>A p.R538K | Missense Mutation (SNP) | VAF 135/499 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.096); catalogued as COSV54959574; called by muse, mutect2, varscan2
- CATSPERD | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 99/321 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs757837954, COSV101062597, COSV67534240; called by muse, mutect2, varscan2
- CBFA2T3 | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 147/508 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs868444231, COSV51927103; called by muse, mutect2, varscan2
- CCDC141 | c.3520G>A p.E1174K | Missense Mutation (SNP) | VAF 97/300 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs75153675, COSV55374265; called by muse, varscan2
- CCDC27 | c.1592C>T p.T531I | Missense Mutation (SNP) | VAF 90/336 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as rs770714506; called by muse, mutect2, varscan2
- CCDC60 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 125/455 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1372759585, COSV59546299; called by muse, mutect2, varscan2
- CCDC65 | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 51/307 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs145598728; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCL26 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 194/458 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV99139140; called by muse, mutect2, varscan2
- CCR9 | c.43G>A p.D15N (on ENST00000357632 / NM_031200.3; = p.D3N on NM_006641.4) | Missense Mutation (SNP) | VAF 79/224 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs1289723324, COSV62940486; called by muse, mutect2, varscan2
- CDH23 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 123/420 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.428); catalogued as rs562019725, COSV54924513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDR1 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 159/285 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV65164687; called by muse, mutect2, varscan2
- CELSR1 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 128/469 reads (27%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs896065229; called by muse, mutect2, varscan2
- CFAP70 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 85/267 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60283428; called by muse, mutect2, varscan2
- CFAP73 | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 158/549 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763023498, COSV58373449; called by muse, mutect2, varscan2
- CHAD | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 40/388 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs773703642; called by muse, mutect2, varscan2
- CLEC4A | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 167/467 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs745807508, COSV57561565; called by muse, mutect2, varscan2
- CNTN5 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 103/397 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as rs752042635; called by muse, mutect2, varscan2
- CNTNAP2 | c.3482G>A p.G1161E | Missense Mutation (SNP) | VAF 147/486 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.656); catalogued as COSV62179159; called by muse, mutect2, varscan2
- COL2A1 | c.3614C>T p.P1205L | Missense Mutation (SNP) | VAF 104/392 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV61531903; called by muse, mutect2, varscan2
- CPHXL | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 107/364 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.262); catalogued as rs1170689840; called by muse, mutect2, varscan2
- CPZ | c.703G>A p.E235K (on ENST00000360986 / NM_001014447.3; = p.E224K on NM_003652.3) | Missense Mutation (SNP) | VAF 113/391 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.442); catalogued as rs1411209507; called by muse, mutect2, varscan2
- CR2 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 134/439 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763985007, COSV65509504; called by muse, mutect2, varscan2
- CSF1R | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 185/367 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as rs777239066, COSV53842868; called by muse, mutect2, varscan2
- CTSB | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); catalogued as COSV61541090; called by muse, mutect2, varscan2
- CYFIP2 | c.2985G>A p.G995= (on ENST00000616178 / NM_001291722.2; = p.G970= on NM_014376.4) | Splice Region (SNP) | VAF 74/155 reads (48%) | catalogued as COSV59050364; called by muse, mutect2, varscan2
- DIDO1 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 79/338 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as rs779511231, COSV56629053; called by muse, mutect2, varscan2
- DLST | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 64/305 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1412969332; called by muse, mutect2, varscan2
- DNAH10 | c.6965G>A p.W2322* (on ENST00000409039; = p.W2261* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 58/210 reads (28%) | catalogued as COSV68996202; called by muse, mutect2, varscan2
- DNAH10 | c.9052G>A p.D3018N (on ENST00000409039; = p.D2957N on NM_207437.3) | Missense Mutation (SNP) | VAF 109/405 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as COSV101292144, COSV69000109; called by muse, mutect2, varscan2
- DNAH11 | c.13184G>A p.R4395Q | Missense Mutation (SNP) | VAF 78/284 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs368249392, COSV60954764; called by muse, mutect2, varscan2
- DNAH5 | c.8849G>A p.G2950E | Missense Mutation (SNP) | VAF 69/484 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760127558, COSV54246171; called by muse, mutect2, varscan2
- DNAH9 | c.5312G>A p.G1771E | Missense Mutation (SNP) | VAF 118/361 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1169300272; called by muse, mutect2, varscan2
- DOCK3 | c.2155C>T p.R719* | Nonsense Mutation (SNP) | VAF 113/352 reads (32%) | catalogued as rs775338280, COSV56513935; called by muse, mutect2, varscan2
- DSCAML1 | c.5453C>T p.P1818L (on ENST00000321322; = p.P1758L on NM_020693.4) | Missense Mutation (SNP) | VAF 135/327 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs772534456; called by muse, mutect2, varscan2
- DSG4 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 97/273 reads (36%) | catalogued as rs1384407099, COSV57390566; called by muse, mutect2, varscan2
- DYTN | c.1280G>A p.G427E | Missense Mutation (SNP) | VAF 106/382 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV71752282; called by muse, mutect2, varscan2
- ECI1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 123/420 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.626); catalogued as rs1299518126; called by muse, mutect2, varscan2
- ENAM | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 30/454 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68535210; called by muse, mutect2
- ESRP1 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 95/337 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as rs757908275, COSV64411157; called by muse, mutect2, varscan2
- EXD2 | c.1336G>A p.E446K (on ENST00000312994 / NM_001193362.1; = p.E321K on NM_018199.3) | Missense Mutation (SNP) | VAF 100/337 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as rs753418619; called by muse, mutect2, varscan2
- FAM184B | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 127/477 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs1007500218, COSV53951997; called by muse, mutect2, varscan2
- FAM186A | c.2068G>A p.A690T | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs934920192; called by muse, mutect2, varscan2
- FAM83B | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 95/349 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.022); catalogued as COSV60922315; called by muse, mutect2, varscan2
- FGD3 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 187/487 reads (38%) | catalogued as COSV61595658; called by muse, mutect2, varscan2
- FGF21 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 110/420 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs961083362; called by muse, mutect2, varscan2
- FLG2 | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 122/420 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs770197697; called by muse, mutect2, varscan2
- FLT3 | c.806G>A p.W269* | Nonsense Mutation (SNP) | VAF 122/473 reads (26%) | catalogued as COSV99607412; called by muse, mutect2, varscan2
- FREM1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as rs772215299, COSV101085775, COSV66518648; called by muse, mutect2, varscan2
- GALNT13 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 83/281 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.052); catalogued as rs868521163, COSV67211168; called by muse, mutect2, varscan2
- GALNTL6 | c.1414G>A p.G472R | Missense Mutation (SNP) | VAF 96/350 reads (27%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.915); catalogued as COSV72489719; called by muse, mutect2, varscan2
- GATAD2A | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 80/322 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs1441947632; called by muse, mutect2, varscan2
- GDAP1L1 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs372694823; called by muse, varscan2
- GK2 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 108/371 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1417995112, COSV62626181; called by muse, mutect2, varscan2
- GLDN | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 149/532 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV100117726; called by muse, mutect2, varscan2
- GLS2 | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs755576770; called by muse, mutect2, varscan2
- GLT1D1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 128/457 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as rs777988195, COSV55882940; called by muse, mutect2, varscan2
- GOLPH3 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 87/513 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs879144248; called by muse, mutect2, varscan2
- GPR26 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 63/247 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.305); catalogued as rs746223270; called by muse, mutect2, varscan2
- GPR39 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 122/476 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); catalogued as rs759193464, COSV61426773; called by muse, mutect2, varscan2
- GPRC6A | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 121/424 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.284); catalogued as rs1562481852, COSV59955869; called by muse, mutect2, varscan2
- GRIN2B | c.3284C>T p.S1095L | Missense Mutation (SNP) | VAF 162/602 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as COSV74205144; called by muse, mutect2, varscan2
- GRM7 | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 113/391 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV63134197; called by muse, mutect2, varscan2
- GRSF1 | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 87/305 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs896285186; called by muse, mutect2, varscan2
- GYPA | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 95/331 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51618883, COSV51632369; called by muse, mutect2, varscan2
- HELLS | c.597T>A p.F199L | Missense Mutation (SNP) | VAF 87/335 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV104381451; called by muse, mutect2, varscan2
- HYDIN | c.10234G>A p.D3412N | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757280905, COSV66889314; called by muse, mutect2, varscan2
- ICE1 | c.5563C>T p.P1855S | Missense Mutation (SNP) | VAF 137/315 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); catalogued as COSV56826130; called by muse, mutect2, varscan2
- IL2RG | c.317T>A p.L106Q | Missense Mutation (SNP) | VAF 163/285 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52147094; called by muse, mutect2, varscan2
- IL7R | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 240/884 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs776441054; called by muse, mutect2, varscan2
- ITPR3 | c.4100C>T p.S1367F | Missense Mutation (SNP) | VAF 140/488 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV65414386; called by muse, mutect2, varscan2
- JCAD | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 142/595 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV64758708; called by muse, mutect2, varscan2
- KIAA1755 | c.3346G>A p.E1116K | Missense Mutation (SNP) | VAF 284/602 reads (47%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.006); catalogued as rs1443311916, COSV54076375; called by muse, mutect2, varscan2
- KIT | c.2063C>T p.S688L | Missense Mutation (SNP) | VAF 118/400 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55399242; called by muse, mutect2, varscan2
- KLRC1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 80/359 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs369792162, COSV61724885; called by muse, mutect2, varscan2
- L1TD1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 86/289 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs758908225; called by muse, mutect2, varscan2
- L3MBTL1 | c.1274G>A p.S425N (on ENST00000418998 / NM_001377303.1; = p.S335N on NM_015478.7) | Missense Mutation (SNP) | VAF 93/360 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.025); catalogued as rs781158638; called by muse, mutect2, varscan2
- LATS1 | c.2983C>T p.R995C | Missense Mutation (SNP) | VAF 117/425 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53587210, COSV99486386; called by muse, mutect2, varscan2
- LILRB1 | c.1694G>A p.R565K (on ENST00000427581; = p.R515K on NM_006669.6) | Missense Mutation (SNP) | VAF 84/388 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as COSV100207594; called by muse, mutect2, varscan2
- LIMCH1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 81/257 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs767081335; called by muse, mutect2, varscan2
- LRRC20 | c.391G>A p.E131K (on ENST00000355790 / NM_207119.3; = p.E81K on NM_018239.4) | Missense Mutation (SNP) | VAF 74/268 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs757588678; called by muse, mutect2, varscan2
- LRRC4B | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 150/547 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.437); catalogued as rs1171779518; called by muse, mutect2, varscan2
- LRRC4C | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 136/439 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53426620; called by muse, mutect2, varscan2
- MARCHF1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 61/226 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56810465; called by muse, mutect2, varscan2
- MBD1 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 105/434 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs1391447151, COSV99495235; called by muse, varscan2
- MMP16 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 99/344 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54156567; called by muse, mutect2, varscan2
- MNDA | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 94/323 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); catalogued as COSV100933296; called by muse, mutect2, varscan2
- MORC1 | c.2216C>T p.S739L | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.162); catalogued as COSV51725027; called by muse, mutect2, varscan2
- MSTO1 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 90/356 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as rs1328796952, COSV55471096; called by muse, mutect2, varscan2
- MTBP | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 99/352 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200198532; called by muse, mutect2, varscan2
- MTSS2 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 181/626 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.373); catalogued as rs747681926; called by muse, mutect2, varscan2
- MUC16 | c.13783C>T p.P4595S | Missense Mutation (SNP) | VAF 108/396 reads (27%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.067); catalogued as rs772002443; called by muse, mutect2, varscan2
- MUC16 | c.11140C>T p.H3714Y | Missense Mutation (SNP) | VAF 81/350 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs867039375, COSV67487590; called by muse, mutect2, varscan2
- MUC4 | c.9460C>T p.P3154S | Missense Mutation (SNP) | VAF 155/763 reads (20%) | SIFT tolerated, low confidence (0.73); PolyPhen possibly damaging (0.65); catalogued as rs1437279062; called by muse, mutect2, varscan2
- MYH4 | c.3431C>T p.S1144F | Missense Mutation (SNP) | VAF 138/562 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV55121998; called by muse, mutect2, varscan2
- MYO18B | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 86/283 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as rs780287472, COSV59124242; called by muse, mutect2, varscan2
- MYO18B | c.6023C>T p.S2008L | Missense Mutation (SNP) | VAF 112/442 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV59131821; called by muse, mutect2, varscan2
- NAP1L2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 141/233 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.412); catalogued as COSV65172271; called by muse, mutect2, varscan2
- NEMP1 | c.763C>T p.L255F (on ENST00000300128 / NM_001130963.2; = p.L182F on NM_015257.3) | Missense Mutation (SNP) | VAF 71/249 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs936443652; called by muse, mutect2, varscan2
- NIN | c.4021C>T p.Q1341* | Nonsense Mutation (SNP) | VAF 88/340 reads (26%) | catalogued as COSV55392388; called by muse, varscan2
- NLRP3 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 98/351 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV60227288, COSV60230215; called by muse, varscan2
- NOTCH2 | c.7081C>T p.Q2361* | Nonsense Mutation (SNP) | VAF 147/491 reads (30%) | catalogued as CM131595, COSV56688520; called by muse, mutect2, varscan2
- NRXN1 | c.2840G>A p.G947E | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100453190; called by muse, mutect2, varscan2
- NSUN7 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 100/368 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773389446, COSV57274610; called by muse, mutect2, varscan2
- OAT | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 125/381 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs767957551, COSV100920434; called by muse, mutect2, varscan2
- OR2A12 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 137/616 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV68821018; called by muse, mutect2, varscan2
- OR2L13 | c.793C>G p.R265G | Missense Mutation (SNP) | VAF 123/414 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV63560530; called by muse, mutect2, varscan2
- OR4A16 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 138/656 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.013); catalogued as rs775163959, COSV59042634; called by muse, mutect2, varscan2
- OR4D1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 117/438 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as rs760207142, COSV52124382; called by muse, mutect2, varscan2
- OR4N5 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 122/369 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV61320110; called by muse, mutect2, varscan2
- OR4S2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 126/278 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56746238; called by muse, mutect2, varscan2
- OR51B2 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 121/485 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs530486626; called by muse, mutect2, varscan2
- OR51G1 | c.771G>A p.M257I | Missense Mutation (SNP) | VAF 132/445 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.411); catalogued as rs139551574; called by muse, mutect2, varscan2
- OR5H1 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 100/346 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63401894; called by muse, mutect2, varscan2
- OR5L2 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 196/443 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs868537440, COSV65723756; called by muse, mutect2, varscan2
- OR5T2 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 294/604 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV57587719; called by muse, mutect2, varscan2
- OR6C4 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 84/288 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV67792973; called by muse, mutect2, varscan2
- OR6N2 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 85/310 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1228692925; called by muse, mutect2, varscan2
- OR8H1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 159/746 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs867315106, COSV57293250; called by muse, mutect2, varscan2
- OSMR | c.249G>A p.G83= | Splice Region (SNP) | VAF 253/416 reads (61%) | catalogued as rs1206371897, COSV57090560; called by muse, mutect2, varscan2
- OTC | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 65/112 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs148660170; called by muse, mutect2, varscan2
- OTOA | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 108/336 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as rs763916468; called by muse, mutect2, varscan2
- PAK4 | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 122/452 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.098); catalogued as rs756166501; called by muse, varscan2
- PAPPA2 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 143/449 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs1427765574, COSV62778615; called by muse, mutect2, varscan2
- PAPPA2 | c.3709C>T p.P1237S | Missense Mutation (SNP) | VAF 145/491 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV62811287; called by muse, mutect2, varscan2
- PASD1 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 180/320 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV64855689; called by muse, mutect2, varscan2
- PCDHB3 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 114/282 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.886); catalogued as COSV50638218; called by muse, mutect2, varscan2
- PCLO | c.9700G>A p.E3234K | Missense Mutation (SNP) | VAF 209/580 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV61623708; called by muse, mutect2, varscan2
- PCSK1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 78/180 reads (43%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1364933057, COSV60734011; called by mutect2, varscan2
- PDE1C | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 79/281 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs947518022; called by muse, mutect2, varscan2
- PIK3C2G | c.4099C>T p.P1367S (on ENST00000676171; = p.P1326S on NM_004570.5) | Missense Mutation (SNP) | VAF 103/275 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV56842153; called by muse, mutect2, varscan2
- PIWIL2 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 85/306 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs749552524, COSV63253057; called by muse, mutect2, varscan2
- PLCB1 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 72/280 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as rs868140397; called by muse, mutect2, varscan2
- PLCB4 | c.2141C>T p.S714L | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1423446451; called by muse, mutect2, varscan2
- PLEK | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 93/380 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs757128294; called by muse, mutect2, varscan2
- PLEKHM2 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 67/273 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs766262284; called by muse, mutect2, varscan2
- PLPP6 | c.593A>C p.D198A | Missense Mutation (SNP) | VAF 136/354 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56304415; called by muse, mutect2, varscan2
- PLXND1 | c.3967C>T p.R1323C | Missense Mutation (SNP) | VAF 78/352 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60711669; called by muse, mutect2
- PNPLA7 | c.3571G>A p.E1191K | Missense Mutation (SNP) | VAF 105/269 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV53006686; called by muse, mutect2, varscan2
- PON3 | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 95/355 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV55698588; called by muse, mutect2, varscan2
- POTED | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.066); catalogued as rs1397750526; called by muse, mutect2, varscan2
- POTEF | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 194/690 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.099); catalogued as COSV100665000; called by muse, mutect2, varscan2
- POU4F2 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 134/520 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs564340231, COSV55584817, COSV55587383; called by muse, mutect2, varscan2
- PRAMEF12 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 86/301 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769755107, COSV63214663; called by muse, mutect2, varscan2
- PRKCZ | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 91/371 reads (25%) | catalogued as COSV66067518; called by muse, mutect2, varscan2
- PTPRB | c.5195G>A p.R1732Q | Missense Mutation (SNP) | VAF 83/286 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99716851; called by muse, mutect2, varscan2
- RELN | c.6536C>T p.S2179F | Missense Mutation (SNP) | VAF 68/359 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV58986470; called by muse, mutect2, varscan2
- RGL4 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 71/268 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as rs1437487100; called by muse, mutect2, varscan2
- RGS12 | c.770G>A p.G257D | Missense Mutation (SNP) | VAF 139/444 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV60907503; called by muse, mutect2, varscan2
- RIPOR1 | c.2956C>T p.L986F (on ENST00000379312 / NM_001193522.2; = p.L982F on NM_024519.4) | Missense Mutation (SNP) | VAF 138/506 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as rs757739492; called by muse, mutect2, varscan2
- RNF40 | c.2191C>T p.R731W | Missense Mutation (SNP) | VAF 148/436 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs146398674; called by muse, mutect2, varscan2
- RP1 | c.2171G>A p.G724E | Missense Mutation (SNP) | VAF 98/346 reads (28%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as CD004583, COSV55111983, COSV99607470; called by muse, mutect2, varscan2
- RUSC2 | c.2756A>G p.Q919R | Missense Mutation (SNP) | VAF 32/623 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.176); catalogued as rs1201384528, COSV63428750; called by muse, mutect2
- SCN2A | c.4503G>A p.M1501I | Missense Mutation (SNP) | VAF 74/283 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV51838634; called by muse, mutect2, varscan2
- SEMA6B | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 80/341 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs753719828; called by muse, mutect2, varscan2
- SERPINB10 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 70/232 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs1337182266; called by muse, mutect2, varscan2
- SETD1A | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 130/427 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.299); catalogued as rs201308430, COSV52687030; called by muse, mutect2, varscan2
- SGMS1 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 120/416 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as rs1293483935, COSV62370323; called by muse, mutect2, varscan2
- SH3BP4 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 82/285 reads (29%) | catalogued as rs1049457439, COSV60642205; called by muse, mutect2, varscan2
- SIRPG | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 104/407 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746738813, COSV53808055; called by muse, mutect2, varscan2
- SLC22A16 | c.1059G>A p.W353* | Nonsense Mutation (SNP) | VAF 105/429 reads (24%) | catalogued as COSV57929565; called by muse, mutect2, varscan2
- SLC44A4 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 132/466 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as rs777084071; called by muse, varscan2
- SLC4A4 | c.1279G>A p.G427R (on ENST00000264485 / NM_001098484.3; = p.G383R on NM_003759.4) | Missense Mutation (SNP) | VAF 107/385 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.617); catalogued as COSV99141305; called by muse, mutect2, varscan2
- SLC9A4 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 120/428 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs866192803; called by muse, mutect2, varscan2
- SMG9 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 79/310 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.245); catalogued as rs781496953; called by muse, mutect2, varscan2
- SMPD1 | c.1657A>T p.T553S | Missense Mutation (SNP) | VAF 163/537 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as CD102289; called by muse, mutect2, varscan2
- SSH2 | c.1612C>T p.H538Y | Missense Mutation (SNP) | VAF 82/335 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as rs755901682; called by muse, mutect2, varscan2
- STMN2 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 63/263 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55219190; called by muse, mutect2, varscan2
- STXBP3 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 90/308 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64182510; called by muse, mutect2, varscan2
- SYT11 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV100851264; called by muse, mutect2, varscan2
- SYT15 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 46/468 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs782326872, COSV65432454; called by muse, mutect2
- TAT | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 89/277 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs773076331; called by muse, mutect2, varscan2
- TET1 | c.3005C>T p.S1002L | Missense Mutation (SNP) | VAF 86/331 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV65390669; called by muse, mutect2, varscan2
- TEX26 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs775005047, COSV66839450; called by muse, mutect2, varscan2
- TIAM2 | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 128/416 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371959316; called by muse, mutect2, varscan2
- TLCD3B | c.22G>C p.G8R | Missense Mutation (SNP) | VAF 101/410 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54226185, COSV99662562; called by muse, mutect2, varscan2
- TMEM200A | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 100/355 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51651960; called by muse, varscan2
- TMEM200A | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51661010; called by muse, varscan2
- TMEM40 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 83/369 reads (22%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.007); catalogued as COSV53146701; called by muse, mutect2, varscan2
- TNIK | c.3013G>A p.E1005K | Missense Mutation (SNP) | VAF 72/276 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as rs745767967, COSV52678585; called by muse, mutect2, varscan2
- TNNT1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 88/329 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV52571919; called by muse, mutect2, varscan2
- TNR | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 63/259 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs771071400, COSV54870164; called by muse, mutect2, varscan2
- TNXB | c.5681G>A p.G1894E (on ENST00000647633; = p.G1647E on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/302 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64482208; called by muse, mutect2, varscan2
- TRIM55 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 101/368 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs367577432; called by muse, mutect2, varscan2
- TRPM3 | c.4829G>A p.R1610K (on ENST00000357533 / NM_001366142.2; = p.R1465K on NM_020952.6) | Missense Mutation (SNP) | VAF 134/316 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs757979183; called by muse, mutect2, varscan2
- TRPM5 | c.3073C>T p.R1025C | Missense Mutation (SNP) | VAF 123/517 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs764176963; called by muse, mutect2, varscan2
- TRPV5 | c.2087G>A p.S696N | Missense Mutation (SNP) | VAF 141/1548 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV54688810; called by muse, mutect2
- TTC22 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 163/587 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV64881458; called by muse, mutect2, varscan2
- TTN | c.49750G>A p.G16584R (on ENST00000591111; = p.G9160R on NM_003319.4) | Missense Mutation (SNP) | VAF 143/430 reads (33%) | PolyPhen possibly damaging (0.9); catalogued as COSV60305944, COSV60349257; called by muse, mutect2, varscan2
- TTN | c.43045C>A p.P14349T (on ENST00000591111; = p.P6925T on NM_003319.4) | Missense Mutation (SNP) | VAF 139/476 reads (29%) | PolyPhen probably damaging (0.999); catalogued as COSV60328147; called by muse, mutect2, varscan2
- TUBA3C | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 135/571 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs962584103, COSV101262793, COSV67138827; called by muse, mutect2, varscan2
- UGT1A4 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 77/386 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs758623915, COSV59392622; called by muse, mutect2, varscan2
- UGT2B28 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as rs764893740, COSV59434197; called by muse, mutect2, varscan2
- UGT3A2 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 114/778 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56928421; called by muse, mutect2, varscan2
- UTP20 | c.3844C>T p.P1282S | Missense Mutation (SNP) | VAF 89/333 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1356663496; called by muse, mutect2, varscan2
- UTP6 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 90/329 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as rs146623373; called by muse, mutect2, varscan2
- WDR81 | c.4939C>T p.H1647Y (on ENST00000409644 / NM_001163809.2; = p.H596Y on NM_152348.4) | Missense Mutation (SNP) | VAF 191/708 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272144442; called by muse, mutect2, varscan2
- WNK3 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 130/214 reads (61%) | catalogued as COSV63613274; called by muse, mutect2, varscan2
- ZBTB7C | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 129/448 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs776489177, COSV59688571; called by muse, mutect2, varscan2
- ZCCHC2 | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.942); catalogued as rs781027557, COSV54036650; called by muse, mutect2, varscan2
- ZDHHC11B | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 71/354 reads (20%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.494); catalogued as COSV66979187; called by muse, mutect2, varscan2
- ZFP42 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 110/482 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1280289939; called by muse, mutect2, varscan2
- ZFR2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 129/444 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV53598723; called by muse, mutect2, varscan2
- ZNF239 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 132/438 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs767053219, COSV60018305; called by muse, mutect2, varscan2
- ZNF318 | c.2105C>T p.P702L | Missense Mutation (SNP) | VAF 81/354 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1188958439; called by muse, mutect2, varscan2
- ZNF407 | c.5945C>T p.P1982L | Missense Mutation (SNP) | VAF 150/483 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as rs746193465, COSV100225379; called by muse, mutect2, varscan2
- ZNF536 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 109/448 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100835461; called by muse, mutect2, varscan2
- ZNF572 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 109/439 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV60002170; called by muse, mutect2, varscan2
- ZNF714 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 72/255 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV52510265; called by muse, mutect2, varscan2
- A4GNT | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 196/464 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AAK1 | c.536T>C p.V179A | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- ABCC3 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- ACTR1B | c.398A>G p.N133S | Missense Mutation (SNP) | VAF 87/357 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ACY3 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 127/405 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- ADAM23 | c.2104G>A p.D702N | Missense Mutation (SNP) | VAF 82/321 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ADAM7 | c.1181C>A p.P394Q | Missense Mutation (SNP) | VAF 114/420 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ADCY10 | c.3094G>A p.E1032K | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ADCY7 | c.403G>T p.V135L | Missense Mutation (SNP) | VAF 114/383 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- AGAP3 | c.1603C>T p.P535S (on ENST00000622464; = p.P571S on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 268/531 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AKAP4 | c.2437G>C p.E813Q | Missense Mutation (SNP) | VAF 100/148 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ALPI | c.551A>G p.N184S | Missense Mutation (SNP) | VAF 117/506 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ANO3 | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 90/304 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ANO8 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.153); called by muse, mutect2
- ANO9 | c.1334+1G>A p.X445_splice | Splice Site (SNP) | VAF 55/209 reads (26%) | called by muse, mutect2, varscan2
- ANXA13 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 81/315 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APAF1 | c.2116C>T p.H706Y (on ENST00000551964 / NM_181861.2; = p.H695Y on NM_001160.3) | Missense Mutation (SNP) | VAF 114/347 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- ARHGAP30 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 123/451 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ASTL | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 143/519 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASXL3 | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 85/318 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATXN2L | c.1805C>T p.S602F | Missense Mutation (SNP) | VAF 153/502 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- AXIN2 | c.481A>T p.I161F | Missense Mutation (SNP) | VAF 125/453 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- B4GALT2 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 147/595 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- BBX | c.1308G>A p.M436I | Missense Mutation (SNP) | VAF 85/328 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BECN2 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 116/462 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BPIFB4 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 123/484 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- BTBD8 | c.2600C>T p.P867L (on ENST00000636805 / NM_001376131.1; = p.P354L on NM_015237.4) | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- BTNL8 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 130/322 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- C18orf63 | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 69/283 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C2CD4B | c.1034G>T p.R345L | Missense Mutation (SNP) | VAF 151/557 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C3orf20 | c.1227C>G p.C409W | Missense Mutation (SNP) | VAF 125/404 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNA1E | c.1195A>T p.N399Y | Missense Mutation (SNP) | VAF 93/330 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- CAMSAP3 | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 116/516 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- CASQ2 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CBWD5 | c.1105C>T p.L369F (on ENST00000382405 / NM_001330668.1; = p.L321F on NM_001024916.3) | Missense Mutation (SNP) | VAF 29/302 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CC2D2A | c.2869A>C p.T957P | Missense Mutation (SNP) | VAF 75/311 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- CCDC172 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC80 | c.1684T>G p.L562V | Missense Mutation (SNP) | VAF 87/352 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- CCN1 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 88/375 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CCT6A | c.616T>C p.L206= | Splice Region (SNP) | VAF 78/279 reads (28%) | called by muse, mutect2, varscan2
- CD1E | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 93/394 reads (24%) | called by muse, mutect2, varscan2
- CDH18 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 127/675 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- CDHR1 | c.2401G>A p.A801T | Missense Mutation (SNP) | VAF 24/678 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.079); called by muse, mutect2
- CEP128 | c.2738T>A p.L913* | Nonsense Mutation (SNP) | VAF 120/370 reads (32%) | called by muse, mutect2, varscan2
- CHD6 | c.6665C>T p.S2222L | Missense Mutation (SNP) | VAF 186/575 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CLEC18B | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 82/537 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNR2 | c.418T>A p.S140T | Missense Mutation (SNP) | VAF 113/415 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL5A1 | c.3160G>A p.G1054R | Missense Mutation (SNP) | VAF 131/308 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COMP | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 127/442 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CRB1 | c.3215A>T p.N1072I | Missense Mutation (SNP) | VAF 123/393 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- DCAF13 | c.71T>C p.V24A | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DLG4 | c.1546C>T p.R516* (on ENST00000399506 / NM_001321075.3; = p.R559* on NM_001365.4) | Nonsense Mutation (SNP) | VAF 117/416 reads (28%) | called by muse, mutect2, varscan2
- DLL1 | c.1036C>T p.L346F | Missense Mutation (SNP) | VAF 95/349 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- DNAH5 | c.3153G>A p.W1051* | Nonsense Mutation (SNP) | VAF 110/506 reads (22%) | called by muse, mutect2, varscan2
- DNAH6 | c.11665G>T p.G3889* | Nonsense Mutation (SNP) | VAF 116/400 reads (29%) | called by muse, mutect2, varscan2
- DOCK6 | c.5225C>T p.S1742F | Missense Mutation (SNP) | VAF 125/446 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- DPRX | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 81/278 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DSEL | c.1613G>A p.W538* | Nonsense Mutation (SNP) | VAF 183/680 reads (27%) | called by muse, mutect2, varscan2
- DSG3 | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 113/470 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- ENPEP | c.1909G>A p.D637N | Missense Mutation (SNP) | VAF 73/295 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ENTPD7 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 71/289 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ERG | c.1421C>T p.P474L (on ENST00000398919 / NM_001243428.1; = p.P450L on NM_004449.4) | Missense Mutation (SNP) | VAF 108/381 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- EXPH5 | c.3656G>A p.G1219E | Missense Mutation (SNP) | VAF 94/261 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- FAM166B | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 108/368 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- FAM83A | c.457C>G p.R153G | Missense Mutation (SNP) | VAF 86/294 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FBN1 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 81/326 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FLG | c.9334G>A p.G3112R | Missense Mutation (SNP) | VAF 144/261 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- FLG2 | c.3463C>T p.Q1155* | Nonsense Mutation (SNP) | VAF 107/385 reads (28%) | called by muse, mutect2, varscan2
- FLNC | c.8066A>G p.N2689S | Missense Mutation (SNP) | VAF 169/618 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- FMN2 | c.3040C>T p.L1014F | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FOXO3 | c.1693C>T p.L565F | Missense Mutation (SNP) | VAF 72/286 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- FUT6 | c.597G>A p.W199* | Nonsense Mutation (SNP) | VAF 121/514 reads (24%) | called by muse, mutect2, varscan2
- GK3P | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 101/428 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GNB1L | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 128/402 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPRC6A | c.707A>C p.N236T | Missense Mutation (SNP) | VAF 103/441 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- GREB1 | c.458T>G p.F153C | Missense Mutation (SNP) | VAF 61/243 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIA1 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 130/325 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- GUCA2B | c.325A>G p.T109A | Missense Mutation (SNP) | VAF 125/405 reads (31%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HCRTR2 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 126/432 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- HEATR1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 69/223 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HEPH | c.1480G>A p.E494K (on ENST00000343002; = p.E227K on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- HIVEP1 | c.3076C>A p.P1026T | Missense Mutation (SNP) | VAF 102/326 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.169); called by mutect2, varscan2
- IGHE | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 110/487 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGSF1 | c.2575G>A p.E859K | Missense Mutation (SNP) | VAF 91/144 reads (63%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IKBKB | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 98/331 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IREB2 | c.2117C>T p.S706L | Missense Mutation (SNP) | VAF 63/240 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- KCNN4 | c.278T>C p.L93P | Missense Mutation (SNP) | VAF 29/546 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2
- KHSRP | c.1371del p.F457Lfs*2 | Frame Shift Del (DEL) | VAF 117/471 reads (25%) | called by mutect2, pindel, varscan2
- KIAA0100 | c.6653_6654insC p.L2218Ffs*31 | Frame Shift Ins (INS) | VAF 101/420 reads (24%) | called by mutect2, pindel, varscan2
- KIAA1958 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 128/326 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KLHDC7A | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 138/487 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- KLHL10 | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 77/300 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT36 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 103/344 reads (30%) | called by muse, mutect2, varscan2
- KRT81 | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 90/268 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRTAP16-1 | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 161/638 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- KRTAP9-4 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 196/592 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- L1TD1 | c.1969G>A p.D657N | Missense Mutation (SNP) | VAF 67/295 reads (23%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- LMO7 | c.4640C>T p.P1547L (on ENST00000357063; = p.P1228L on NM_005358.5) | Missense Mutation (SNP) | VAF 147/495 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC17 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 359/540 reads (66%) | SIFT tolerated (0.18); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LRRC4C | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 87/321 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LTF | c.1919G>A p.G640E | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MACF1 | c.9034G>T p.D3012Y | Missense Mutation (SNP) | VAF 84/307 reads (27%) | called by muse, mutect2, varscan2
- MAGEE2 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 121/227 reads (53%) | SIFT tolerated (1); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- MAN1A1 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 26/500 reads (5%) | called by muse, mutect2
- MAP2 | c.1807C>T p.H603Y | Missense Mutation (SNP) | VAF 70/308 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- MAP3K8 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 68/298 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAPKBP1 | c.1900G>A p.G634S (on ENST00000456763 / NM_001128608.2; = p.G628S on NM_014994.3) | Missense Mutation (SNP) | VAF 81/347 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MME | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 69/292 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- MORC1 | c.2509C>T p.Q837* | Nonsense Mutation (SNP) | VAF 58/252 reads (23%) | called by muse, mutect2, varscan2
- MTF1 | c.1303_1304del p.L435Tfs*46 | Frame Shift Del (DEL) | VAF 112/440 reads (25%) | called by mutect2, pindel, varscan2
- MUC16 | c.40879C>T p.P13627S | Missense Mutation (SNP) | VAF 85/326 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MUC16 | c.14179G>A p.D4727N | Missense Mutation (SNP) | VAF 103/385 reads (27%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH15 | c.3913G>A p.E1305K | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2
- MYO18B | c.1879G>A p.G627S | Missense Mutation (SNP) | VAF 110/393 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- NDUFA11 | c.157G>T p.V53L | Missense Mutation (SNP) | VAF 85/345 reads (25%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- NDUFAF1 | c.80T>G p.F27C | Missense Mutation (SNP) | VAF 72/374 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.43); called by muse, mutect2
- NEURL3 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 66/297 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- NFKBIE | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 156/513 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NHLRC1 | c.952T>A p.S318T | Missense Mutation (SNP) | VAF 114/439 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NIBAN1 | c.2059G>A p.G687R | Missense Mutation (SNP) | VAF 151/511 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- NLRP13 | c.1238G>A p.R413K | Missense Mutation (SNP) | VAF 64/288 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.109); called by mutect2, varscan2
- NNT | c.1963G>T p.V655F | Missense Mutation (SNP) | VAF 136/640 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NPM2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 83/327 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- NUDT8 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 111/382 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUP155 | c.3460C>T p.Q1154* (on ENST00000231498 / NM_153485.3; = p.Q1095* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 211/399 reads (53%) | called by muse, mutect2, varscan2
- NUP210L | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 102/318 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- NXPE4 | c.128T>C p.L43P | Missense Mutation (SNP) | VAF 20/309 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2
- OLFM2 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 131/430 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- OR14C36 | c.398T>A p.I133N | Missense Mutation (SNP) | VAF 120/368 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR2D2 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 75/298 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- OR5H15 | c.519A>G p.I173M | Missense Mutation (SNP) | VAF 79/314 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- OTUD7B | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 134/507 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- P4HA3 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 111/578 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- PAK6 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 132/420 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- PARP12 | c.1759C>T p.H587Y | Missense Mutation (SNP) | VAF 20/805 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PATL1 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 125/411 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); called by muse, varscan2
- PCDH8 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA1 | c.748C>T p.H250Y | Missense Mutation (SNP) | VAF 122/308 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- PCDHB4 | c.269A>C p.D90A | Missense Mutation (SNP) | VAF 26/327 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PGGHG | c.2066C>T p.S689L | Missense Mutation (SNP) | VAF 138/434 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PHACTR2 | c.1681C>A p.L561M | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- PITPNM3 | c.2084G>A p.G695D | Missense Mutation (SNP) | VAF 178/557 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- PKHD1L1 | c.3076C>A p.Q1026K | Missense Mutation (SNP) | VAF 66/306 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by mutect2, varscan2
- PKP4 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLB1 | c.3398G>A p.G1133E | Missense Mutation (SNP) | VAF 102/372 reads (27%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PNLIPRP2 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POLH | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 112/379 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAMEF14 | c.294G>A p.W98* | Nonsense Mutation (SNP) | VAF 68/252 reads (27%) | called by muse, mutect2, varscan2
- PRG4 | c.2498A>T p.E833V | Missense Mutation (SNP) | VAF 152/503 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- PRX | c.3622G>T p.E1208* | Nonsense Mutation (SNP) | VAF 129/492 reads (26%) | called by muse, mutect2, varscan2
- PSG1 | c.1063T>A p.S355T | Missense Mutation (SNP) | VAF 82/363 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- PSMD3 | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 80/306 reads (26%) | called by muse, mutect2, varscan2
- PTPRQ | c.4135G>A p.E1379K (on ENST00000616559; = p.E1337K on NM_001145026.2) | Missense Mutation (SNP) | VAF 86/241 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PTPRU | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 100/357 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- QRICH2 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 131/459 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- RAD51AP2 | c.2596C>T p.P866S | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RANBP2 | c.6059C>T p.P2020L | Missense Mutation (SNP) | VAF 81/398 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- REELD1 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 81/332 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- RHBDF1 | c.1066A>T p.I356F | Missense Mutation (SNP) | VAF 190/740 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- RNF31 | c.1798C>T p.Q600* | Nonsense Mutation (SNP) | VAF 85/394 reads (22%) | called by muse, mutect2, varscan2
- RP1 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- RTN4R | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 135/499 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SAMD15 | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 106/393 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- SARS2 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 99/293 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SATB2 | c.1865C>T p.S622F | Missense Mutation (SNP) | VAF 133/452 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SCMH1 | c.1772C>T p.S591F (on ENST00000326197 / NM_001031694.2; = p.S522F on NM_012236.4) | Missense Mutation (SNP) | VAF 111/431 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- SCN2A | c.1104C>A p.D368E | Missense Mutation (SNP) | VAF 85/386 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEMA3E | c.2131A>G p.K711E | Missense Mutation (SNP) | VAF 136/682 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SETD2 | c.3704T>G p.L1235W | Missense Mutation (SNP) | VAF 125/496 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- SHANK3 | c.4895C>T p.P1632L | Missense Mutation (SNP) | VAF 134/527 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SIGLEC1 | c.607C>T p.H203Y | Missense Mutation (SNP) | VAF 142/468 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SLC16A9 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 103/377 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- SLC22A2 | c.1142T>C p.F381S | Missense Mutation (SNP) | VAF 37/434 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- SLC25A26 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 78/297 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC39A12 | c.894G>C p.E298D | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SLCO1C1 | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 165/408 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMC1B | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SMC3 | c.1570A>T p.I524L | Missense Mutation (SNP) | VAF 82/356 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SP1 | c.1525G>T p.A509S (on ENST00000327443 / NM_138473.3; = p.A502S on NM_003109.1) | Missense Mutation (SNP) | VAF 143/423 reads (34%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SP5 | c.956G>T p.W319L | Missense Mutation (SNP) | VAF 174/577 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- SRP72 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 65/337 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ST18 | c.277+1G>A p.X93_splice | Splice Site (SNP) | VAF 74/299 reads (25%) | called by muse, mutect2, varscan2
- ST3GAL2 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 80/324 reads (25%) | PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ST6GAL2 | c.800C>T p.T267I | Missense Mutation (SNP) | VAF 187/542 reads (35%) | PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- STARD9 | c.6392G>C p.G2131A | Missense Mutation (SNP) | VAF 101/374 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- STK31 | c.2947C>T p.P983S | Missense Mutation (SNP) | VAF 116/384 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- STON1 | c.371T>G p.L124R | Missense Mutation (SNP) | VAF 111/357 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- STX19 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 68/312 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- STYXL2 | c.2867G>A p.G956E | Missense Mutation (SNP) | VAF 91/308 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SUPT20H | c.2248G>C p.A750P (on ENST00000350612 / NM_001014286.3; = p.S716T on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/411 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SV2C | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 112/245 reads (46%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TANGO6 | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 125/430 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D9 | c.2248C>T p.P750S | Missense Mutation (SNP) | VAF 81/323 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- TDRD5 | c.2357C>T p.S786F | Missense Mutation (SNP) | VAF 68/234 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TDRD9 | c.3205C>T p.Q1069* | Nonsense Mutation (SNP) | VAF 114/391 reads (29%) | called by muse, mutect2, varscan2
- TENM1 | c.1079G>T p.G360V | Missense Mutation (SNP) | VAF 135/236 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- THADA | c.1750T>A p.S584T | Missense Mutation (SNP) | VAF 95/325 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- THAP4 | c.1402T>C p.F468L | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TMCO2 | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 149/447 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM151A | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 157/498 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- TMPRSS3 | c.818G>A p.G273D | Missense Mutation (SNP) | VAF 68/286 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNFRSF11A | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 160/526 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- TRANK1 | c.6970G>A p.E2324K | Missense Mutation (SNP) | VAF 138/424 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRANK1 | c.5167C>T p.Q1723* | Nonsense Mutation (SNP) | VAF 67/289 reads (23%) | called by muse, mutect2, varscan2
- TRPM1 | c.2517G>C p.L839F | Missense Mutation (SNP) | VAF 99/341 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- TRPM7 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 59/275 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSPAN32 | c.11G>A p.W4* | Nonsense Mutation (SNP) | VAF 24/506 reads (5%) | called by muse, mutect2
- TSPAN32 | c.12G>A p.W4* | Nonsense Mutation (SNP) | VAF 24/510 reads (5%) | called by muse, mutect2
- UGT2A1 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 123/394 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- UNC93B1 | c.1702G>A p.G568R | Missense Mutation (SNP) | VAF 322/714 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, varscan2
- UPP2 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- USP53 | c.1709G>A p.G570E | Missense Mutation (SNP) | VAF 103/324 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- VCAN | c.6589C>T p.P2197S | Missense Mutation (SNP) | VAF 174/366 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- WDR17 | c.1318T>G p.Y440D | Missense Mutation (SNP) | VAF 67/261 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- XRRA1 | c.1630A>G p.T544A | Missense Mutation (SNP) | VAF 114/527 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZBBX | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZBTB1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 71/350 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- ZC3H6 | c.2536G>A p.G846S | Missense Mutation (SNP) | VAF 80/352 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZC3H6 | c.2537G>A p.G846D | Missense Mutation (SNP) | VAF 82/353 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- ZFHX3 | c.5914G>A p.G1972R | Missense Mutation (SNP) | VAF 83/399 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFP42 | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 112/483 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF148 | c.2348C>T p.S783F | Missense Mutation (SNP) | VAF 70/273 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- ZNF48 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 139/445 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZNF492 | c.19A>G p.N7D | Missense Mutation (SNP) | VAF 70/345 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF518A | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 96/398 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF530 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 101/356 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF749 | c.1294C>T p.H432Y | Missense Mutation (SNP) | VAF 106/398 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF768 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 162/547 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZSCAN10 | c.214A>G p.S72G (on ENST00000252463; = p.S127G on NM_032805.3) | Missense Mutation (SNP) | VAF 30/490 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- ABCC6 | c.1470C>T p.L490= | Silent (SNP) | VAF 142/518 reads (27%) | called by muse, mutect2, varscan2
- ABCD4 | c.72C>T p.F24= | Silent (SNP) | VAF 85/317 reads (27%) | catalogued as rs1266515130; ClinVar: likely benign; called by muse, mutect2, varscan2
- ABHD16B | c.354G>A p.L118= | Silent (SNP) | VAF 153/534 reads (29%) | called by muse, mutect2, varscan2
- ACAN | c.2763G>A p.G921= | Silent (SNP) | VAF 115/429 reads (27%) | catalogued as rs750489449, COSV61357185; called by muse, mutect2, varscan2
- ADA | c.804C>T p.L268= | Silent (SNP) | VAF 102/358 reads (28%) | called by muse, mutect2, varscan2
- ADAM11 | c.783C>T p.L261= | Silent (SNP) | VAF 92/339 reads (27%) | called by muse, mutect2, varscan2
- ADAM2 | c.1149G>A p.Q383= | Silent (SNP) | VAF 118/468 reads (25%) | catalogued as COSV55869492; called by muse, mutect2, varscan2
- ADAM7 | c.1500C>T p.F500= | Silent (SNP) | VAF 113/383 reads (30%) | catalogued as COSV51535973; called by muse, mutect2, varscan2
- ADGRF5 | c.3886C>T p.L1296= | Silent (SNP) | VAF 69/250 reads (28%) | catalogued as rs1338779302; called by muse, mutect2, varscan2
- AHNAK | c.11328T>C p.G3776= | Silent (SNP) | VAF 164/525 reads (31%) | catalogued as rs1230293092; called by muse, mutect2, varscan2
- ALDH2 | c.267G>A p.L89= | Silent (SNP) | VAF 136/571 reads (24%) | catalogued as COSV99923061; called by muse, mutect2, varscan2
- ALMS1 | c.11457C>T p.Y3819= | Silent (SNP) | VAF 274/662 reads (41%) | catalogued as rs373397289, CM040369; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKRD28 | c.2343C>T p.F781= | Silent (SNP) | VAF 75/261 reads (29%) | called by muse, mutect2, varscan2
- ANXA13 | c.915G>A p.G305= | Silent (SNP) | VAF 81/313 reads (26%) | catalogued as rs560541609; called by muse, mutect2, varscan2
- ARMC10 | c.930C>T p.F310= | Silent (SNP) | VAF 98/622 reads (16%) | catalogued as rs1340690295, COSV100085831; called by muse, mutect2, varscan2
- ARMC4 | c.999G>A p.K333= | Silent (SNP) | VAF 103/352 reads (29%) | called by muse, mutect2, varscan2
- ASIC1 | c.660C>T p.I220= | Silent (SNP) | VAF 120/377 reads (32%) | catalogued as COSV99948258; called by muse, mutect2, varscan2
- ASTN1 | c.309C>T p.I103= | Silent (SNP) | VAF 77/299 reads (26%) | catalogued as COSV56061591; called by muse, mutect2, varscan2
- ATP12A | c.3036C>T p.I1012= | Silent (SNP) | VAF 97/378 reads (26%) | called by muse, mutect2, varscan2
- AXIN2 | c.483C>T p.I161= | Silent (SNP) | VAF 126/451 reads (28%) | called by muse, mutect2
- B3GALT6 | c.489G>A p.L163= | Silent (SNP) | VAF 26/618 reads (4%) | catalogued as rs1305970798; called by muse, mutect2
- BACE2 | c.780A>G p.K260= | Silent (SNP) | VAF 91/351 reads (26%) | catalogued as rs1317679169; called by muse, mutect2, varscan2
- BAHD1 | c.1692C>T p.A564= | Silent (SNP) | VAF 181/641 reads (28%) | called by muse, mutect2, varscan2
- BEGAIN | c.591C>T p.S197= | Silent (SNP) | VAF 189/615 reads (31%) | called by muse, mutect2, varscan2
- BRD4 | c.2037G>A p.R679= | Silent (SNP) | VAF 25/284 reads (9%) | called by muse, mutect2
- BRINP2 | c.2274G>A p.R758= | Silent (SNP) | VAF 96/339 reads (28%) | catalogued as COSV64175680; called by muse, mutect2, varscan2
- C1orf158 | c.483T>C p.T161= | Silent (SNP) | VAF 120/387 reads (31%) | called by muse, mutect2, varscan2
- CALCRL | c.1183C>T p.L395= | Silent (SNP) | VAF 69/228 reads (30%) | catalogued as COSV66476655; called by muse, mutect2, varscan2
- CCDC168 | c.1539A>G p.L513= | Silent (SNP) | VAF 72/290 reads (25%) | called by muse, mutect2, varscan2
- CCN4 | c.684C>G p.T228= | Silent (SNP) | VAF 19/518 reads (4%) | called by muse, mutect2
- CD1E | c.291C>T p.F97= | Silent (SNP) | VAF 93/396 reads (23%) | called by muse, mutect2, varscan2
- CDR2 | c.1095G>A p.K365= | Silent (SNP) | VAF 139/430 reads (32%) | catalogued as rs1457745728; called by muse, mutect2, varscan2
- CELSR1 | c.5337C>T p.I1779= | Silent (SNP) | VAF 118/405 reads (29%) | catalogued as rs750903620, COSV53097400, COSV53101072; called by muse, mutect2, varscan2
- CFC1 | c.240C>T p.F80= | Silent (SNP) | VAF 94/753 reads (12%) | catalogued as rs762056382, COSV52090345, COSV52090471; called by muse, mutect2, varscan2
- CFTR | c.807C>T p.I269= | Silent (SNP) | VAF 214/425 reads (50%) | catalogued as COSV50043964; called by muse, mutect2, varscan2
- CHRNA2 | c.891C>T p.I297= | Silent (SNP) | VAF 138/506 reads (27%) | called by muse, mutect2, varscan2
- COL20A1 | c.507G>A p.Q169= | Silent (SNP) | VAF 120/452 reads (27%) | called by muse, mutect2, varscan2
- COL6A1 | c.423C>T p.L141= | Silent (SNP) | VAF 56/233 reads (24%) | catalogued as rs373486149; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- COL8A1 | c.837C>T p.F279= | Silent (SNP) | VAF 112/413 reads (27%) | called by muse, mutect2, varscan2
- COL9A2 | c.465G>A p.G155= | Silent (SNP) | VAF 139/436 reads (32%) | called by muse, mutect2, varscan2
- CRAT | c.171C>T p.I57= | Silent (SNP) | VAF 145/319 reads (45%) | catalogued as rs1006252208, COSV100533988; called by muse, mutect2, varscan2
- CRB1 | c.3216C>T p.N1072= | Silent (SNP) | VAF 122/397 reads (31%) | catalogued as COSV100957954; called by muse, mutect2, varscan2
- CREBBP | c.513T>C p.T171= | Silent (SNP) | VAF 136/474 reads (29%) | called by muse, mutect2, varscan2
- CROCC | c.894C>T p.L298= | Silent (SNP) | VAF 79/267 reads (30%) | catalogued as rs974448213; called by muse, mutect2, varscan2
- CRX | c.270G>A p.R90= | Silent (SNP) | VAF 64/297 reads (22%) | catalogued as COSV55757133; called by muse, mutect2, varscan2
- CUL9 | c.3777C>T p.S1259= | Silent (SNP) | VAF 102/359 reads (28%) | called by muse, mutect2, varscan2
- CUX2 | c.1152C>T p.L384= | Silent (SNP) | VAF 100/446 reads (22%) | called by muse, mutect2, varscan2
- CXCR1 | c.948C>T p.F316= | Silent (SNP) | VAF 100/391 reads (26%) | catalogued as rs753246147, COSV55281049; called by muse, mutect2, varscan2
- CYLC1 | c.1737C>T p.F579= | Silent (SNP) | VAF 123/236 reads (52%) | called by muse, mutect2, varscan2
- CYP4B1 | c.354C>T p.F118= | Silent (SNP) | VAF 86/333 reads (26%) | catalogued as rs867323780; called by muse, mutect2, varscan2
- CYP4F12 | c.1137C>T p.P379= | Silent (SNP) | VAF 57/247 reads (23%) | called by muse, mutect2, varscan2
- CYP4F8 | c.735C>T p.F245= | Silent (SNP) | VAF 99/379 reads (26%) | catalogued as COSV100358060; called by muse, mutect2, varscan2
- DCAF4L1 | c.174G>A p.K58= | Silent (SNP) | VAF 106/358 reads (30%) | called by muse, mutect2, varscan2
- DHX8 | c.2184C>T p.Y728= | Silent (SNP) | VAF 112/406 reads (28%) | called by muse, mutect2, varscan2
- DISP3 | c.2481C>T p.F827= | Silent (SNP) | VAF 78/267 reads (29%) | catalogued as COSV53824346; called by muse, mutect2, varscan2
- DNAH10 | c.4197G>A p.L1399= (on ENST00000409039; = p.L1338= on NM_207437.3) | Silent (SNP) | VAF 83/315 reads (26%) | catalogued as COSV69004754; called by muse, mutect2, varscan2
- DNAH2 | c.3267G>A p.E1089= | Silent (SNP) | VAF 145/445 reads (33%) | catalogued as rs375299889; called by muse, mutect2, varscan2
- DNHD1 | c.4318C>T p.L1440= | Silent (SNP) | VAF 120/478 reads (25%) | called by muse, mutect2, varscan2
- DSCAM | c.2568G>A p.V856= | Silent (SNP) | VAF 68/237 reads (29%) | called by muse, mutect2, varscan2
- DTX4 | c.1128C>T p.S376= | Silent (SNP) | VAF 94/340 reads (28%) | called by muse, mutect2, varscan2
- EML1 | c.1605C>T p.F535= | Silent (SNP) | VAF 67/239 reads (28%) | called by muse, mutect2, varscan2
- EML6 | c.3028C>T p.L1010= | Silent (SNP) | VAF 22/472 reads (5%) | called by muse, mutect2
- EP300 | c.3792C>T p.I1264= | Silent (SNP) | VAF 73/312 reads (23%) | called by muse, mutect2, varscan2
- EPHB2 | c.1575C>T p.F525= | Silent (SNP) | VAF 71/263 reads (27%) | catalogued as COSV65861701; called by muse, mutect2, varscan2
- EPPK1 | c.5055C>T p.I1685= | Silent (SNP) | VAF 218/809 reads (27%) | catalogued as rs782533658, COSV73261205; called by muse, mutect2, varscan2
- ERICH3 | c.1272G>A p.L424= | Silent (SNP) | VAF 101/388 reads (26%) | catalogued as COSV58604007; called by muse, mutect2, varscan2
- FAHD2B | c.906G>A p.E302= | Silent (SNP) | VAF 73/454 reads (16%) | called by muse, mutect2, varscan2
- FAM149A | c.1002C>T p.V334= (on ENST00000356371 / NM_001367768.2; = p.V43= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 99/374 reads (26%) | called by muse, mutect2, varscan2
- FAM166B | c.780C>A p.T260= | Silent (SNP) | VAF 108/366 reads (30%) | called by muse, mutect2, varscan2
- FAM47B | c.792C>A p.P264= | Silent (SNP) | VAF 18/292 reads (6%) | called by muse, mutect2
- FIP1L1 | c.849T>C p.T283= | Silent (SNP) | VAF 70/242 reads (29%) | called by muse, mutect2, varscan2
- FMO1 | c.222C>T p.F74= | Silent (SNP) | VAF 104/375 reads (28%) | called by muse, mutect2, varscan2
- FOLR3 | c.366G>A p.Q122= | Silent (SNP) | VAF 79/333 reads (24%) | called by muse, mutect2, varscan2
- FPR2 | c.924C>T p.D308= | Silent (SNP) | VAF 95/366 reads (26%) | called by muse, mutect2, varscan2
- GALNT9 | c.498C>T p.V166= | Silent (SNP) | VAF 118/438 reads (27%) | called by muse, mutect2, varscan2
- GCC2 | c.1626A>G p.G542= | Silent (SNP) | VAF 102/379 reads (27%) | catalogued as rs1305544670; called by muse, mutect2, varscan2
- GINM1 | c.648A>C p.V216= | Silent (SNP) | VAF 89/312 reads (29%) | called by muse, mutect2, varscan2
- GJD2 | c.682T>C p.L228= | Silent (SNP) | VAF 128/430 reads (30%) | catalogued as rs1379230828, COSV51747306; called by muse, mutect2, varscan2
- GLS2 | c.177G>A p.Q59= | Silent (SNP) | VAF 93/378 reads (25%) | called by muse, mutect2, varscan2
- GPR137C | c.69C>T p.P23= | Silent (SNP) | VAF 128/448 reads (29%) | called by muse, mutect2, varscan2
- GPR68 | c.669G>A p.K223= | Silent (SNP) | VAF 159/505 reads (31%) | called by muse, mutect2, varscan2
- GRIA3 | c.669C>T p.V223= | Silent (SNP) | VAF 98/164 reads (60%) | catalogued as rs751784028, COSV52079963; called by muse, mutect2, varscan2
- GRIN2A | c.4101C>T p.F1367= | Silent (SNP) | VAF 119/441 reads (27%) | catalogued as COSV58029731; called by muse, mutect2, varscan2
- GRM7 | c.2037G>A p.R679= | Silent (SNP) | VAF 123/370 reads (33%) | called by muse, mutect2, varscan2
- GSC2 | c.510G>A p.V170= | Silent (SNP) | VAF 70/315 reads (22%) | called by muse, mutect2, varscan2
- H1-3 | c.84C>T p.G28= | Silent (SNP) | VAF 127/411 reads (31%) | catalogued as rs758111146; called by muse, mutect2, varscan2
- HERC4 | c.1728C>T p.I576= | Silent (SNP) | VAF 63/329 reads (19%) | catalogued as rs757377501, COSV99516326; called by muse, mutect2, varscan2
- HGFAC | c.1707C>T p.S569= | Silent (SNP) | VAF 129/502 reads (26%) | called by muse, mutect2, varscan2
- HIVEP2 | c.4977T>C p.Y1659= | Silent (SNP) | VAF 106/379 reads (28%) | called by muse, mutect2, varscan2
- HOXA4 | c.957C>T p.S319= | Silent (SNP) | VAF 69/216 reads (32%) | called by muse, mutect2, varscan2
- HSPA12B | c.696G>A p.E232= | Silent (SNP) | VAF 85/313 reads (27%) | catalogued as COSV54765767; called by muse, mutect2, varscan2
- HSPB3 | c.138G>A p.R46= | Silent (SNP) | VAF 166/367 reads (45%) | called by muse, mutect2, varscan2
- HYDIN | c.6294C>G p.S2098= | Silent (SNP) | VAF 78/258 reads (30%) | catalogued as rs371667050; called by muse, mutect2, varscan2
- IGHE | c.381C>T p.F127= | Silent (SNP) | VAF 73/475 reads (15%) | catalogued as rs868912888; called by muse, mutect2, varscan2
- IGHV3-53 | c.27C>T p.F9= | Silent (SNP) | VAF 15/124 reads (12%) | catalogued as rs1555545328; called by muse, mutect2
- IGKV1-9 | c.96C>T p.F32= | Silent (SNP) | VAF 102/361 reads (28%) | catalogued as rs752555494; called by muse, mutect2, varscan2
- IKZF2 | c.975C>T p.I325= | Silent (SNP) | VAF 118/433 reads (27%) | called by muse, mutect2, varscan2
- INPP5B | c.339C>T p.P113= | Silent (SNP) | VAF 96/316 reads (30%) | called by muse, mutect2, varscan2
- ITGA4 | c.384G>A p.G128= | Silent (SNP) | VAF 77/372 reads (21%) | catalogued as rs745686958; called by muse, mutect2, varscan2
- ITGA7 | c.153C>T p.L51= | Silent (SNP) | VAF 122/403 reads (30%) | called by muse, mutect2, varscan2
- ITGB3 | c.1521C>T p.S507= | Silent (SNP) | VAF 141/486 reads (29%) | called by muse, mutect2, varscan2
- JAK1 | c.1725C>T p.F575= | Silent (SNP) | VAF 82/328 reads (25%) | catalogued as rs1343180276, COSV61096838; called by muse, mutect2, varscan2
- KCNN3 | c.1506G>A p.Q502= (on ENST00000618040 / NM_001204087.1; = p.Q487= on NM_002249.6) | Silent (SNP) | VAF 72/278 reads (26%) | catalogued as COSV55221174; called by muse, mutect2, varscan2
- KCNQ2 | c.2202G>A p.G734= (on ENST00000359125 / NM_172107.4; = p.G706= on NM_004518.6) | Silent (SNP) | VAF 210/750 reads (28%) | called by muse, mutect2, varscan2
- KCNU1 | c.2892G>A p.G964= | Silent (SNP) | VAF 113/372 reads (30%) | called by muse, mutect2, varscan2
- KDR | c.3054C>T p.F1018= | Silent (SNP) | VAF 94/302 reads (31%) | catalogued as rs747809879; called by muse, mutect2, varscan2
- KIF1A | c.381C>T p.F127= | Silent (SNP) | VAF 94/342 reads (27%) | catalogued as COSV57502939; called by muse, mutect2, varscan2
- KLK3 | c.483A>G p.E161= | Silent (SNP) | VAF 80/334 reads (24%) | catalogued as COSV58100124; called by muse, mutect2, varscan2
- KRT16 | c.108C>A p.A36= | Silent (SNP) | VAF 42/860 reads (5%) | called by muse, mutect2
- KRT84 | c.642C>T p.F214= | Silent (SNP) | VAF 120/371 reads (32%) | catalogued as rs1003195648, COSV57770809; called by muse, mutect2, varscan2
- LAMB1 | c.132C>T p.I44= | Silent (SNP) | VAF 117/687 reads (17%) | catalogued as COSV55966999; called by muse, mutect2, varscan2
- LAMP5 | c.717G>A p.L239= | Silent (SNP) | VAF 88/370 reads (24%) | catalogued as COSV55715221, COSV55717773; called by muse, mutect2, varscan2
- LRP1B | c.9903C>T p.P3301= | Silent (SNP) | VAF 119/436 reads (27%) | called by muse, mutect2, varscan2
- LRRC43 | c.825C>T p.A275= | Silent (SNP) | VAF 84/364 reads (23%) | called by muse, mutect2, varscan2
- LSM11 | c.489C>T p.I163= | Silent (SNP) | VAF 128/305 reads (42%) | catalogued as COSV53848209; called by muse, mutect2, varscan2
- LTBP1 | c.1647C>T p.P549= (on ENST00000404816 / NM_206943.4; = p.P223= on NM_000627.4) | Silent (SNP) | VAF 99/409 reads (24%) | catalogued as rs759105216; called by muse, mutect2, varscan2
- MAP2 | c.1806C>T p.V602= | Silent (SNP) | VAF 70/309 reads (23%) | called by muse, varscan2
- MAP3K10 | c.2379C>T p.P793= | Silent (SNP) | VAF 157/491 reads (32%) | catalogued as rs890935904; called by muse, varscan2
- MAP3K20 | c.2319C>T p.Y773= | Silent (SNP) | VAF 122/440 reads (28%) | catalogued as rs1224675905; called by muse, mutect2, varscan2
- MARK4 | c.138C>T p.I46= | Silent (SNP) | VAF 146/591 reads (25%) | catalogued as rs570301106; called by muse, mutect2, varscan2
- METTL2A | c.543C>T p.T181= | Silent (SNP) | VAF 20/73 reads (27%) | called by muse, mutect2, varscan2
- METTL2B | c.543C>T p.T181= | Silent (SNP) | VAF 62/538 reads (12%) | called by muse, mutect2, varscan2
- MFSD9 | c.1284C>T p.L428= | Silent (SNP) | VAF 151/527 reads (29%) | called by muse, mutect2, varscan2
- MIEF1 | c.1224C>T p.F408= | Silent (SNP) | VAF 139/485 reads (29%) | catalogued as COSV57480398; called by muse, mutect2, varscan2
- MITF | c.1144T>C p.L382= (on ENST00000448226 / NM_006722.3; = p.L282= on NM_000248.4) | Silent (SNP) | VAF 87/380 reads (23%) | called by muse, mutect2, varscan2
- MNDA | c.741C>T p.F247= | Silent (SNP) | VAF 125/406 reads (31%) | called by muse, mutect2, varscan2
- MOB1B | c.84C>T p.L28= | Silent (SNP) | VAF 103/370 reads (28%) | called by muse, mutect2, varscan2
- MORC2 | c.2127T>G p.V709= (on ENST00000397641 / NM_001303256.3; = p.V647= on NM_014941.3) | Silent (SNP) | VAF 108/370 reads (29%) | catalogued as COSV53203717; called by muse, mutect2, varscan2
- MTUS2 | c.2277C>T p.F759= | Silent (SNP) | VAF 113/421 reads (27%) | called by muse, mutect2, varscan2
- MUC16 | c.29838C>T p.S9946= | Silent (SNP) | VAF 127/404 reads (31%) | catalogued as rs1270253484; called by muse, mutect2, varscan2
- MUC16 | c.25344C>T p.V8448= | Silent (SNP) | VAF 156/493 reads (32%) | catalogued as COSV67457564; called by muse, mutect2, varscan2
- MUC4 | c.8775G>A p.Q2925= | Silent (SNP) | VAF 174/694 reads (25%) | catalogued as COSV57762790; called by muse, varscan2
- MUC5B | c.5664C>T p.T1888= | Silent (SNP) | VAF 41/521 reads (8%) | called by muse, mutect2
- MYBPC2 | c.1215C>T p.I405= | Silent (SNP) | VAF 117/488 reads (24%) | catalogued as COSV63098341; called by muse, mutect2, varscan2
- MYO18B | c.3852C>T p.L1284= | Silent (SNP) | VAF 82/399 reads (21%) | called by muse, mutect2
- MYOF | c.4941C>T p.S1647= | Silent (SNP) | VAF 85/314 reads (27%) | called by muse, mutect2, varscan2
- MYRFL | c.1926G>A p.T642= | Silent (SNP) | VAF 28/136 reads (21%) | catalogued as rs977592365; called by muse, mutect2, varscan2
- NARS2 | c.168G>A p.Q56= | Silent (SNP) | VAF 76/432 reads (18%) | called by muse, mutect2, varscan2
- NCAPG | c.1125C>T p.I375= | Silent (SNP) | VAF 45/157 reads (29%) | called by muse, mutect2, varscan2
- NIN | c.4020C>T p.V1340= | Silent (SNP) | VAF 98/370 reads (26%) | catalogued as rs772362180, COSV99814199; called by muse, mutect2, varscan2
- NLRP4 | c.1929C>T p.L643= | Silent (SNP) | VAF 126/461 reads (27%) | called by muse, mutect2, varscan2
- NLRP8 | c.969G>A p.T323= | Silent (SNP) | VAF 113/405 reads (28%) | catalogued as rs753842717, COSV52591458; called by muse, mutect2, varscan2
- NPAT | c.3688C>T p.L1230= | Silent (SNP) | VAF 127/303 reads (42%) | catalogued as rs778785853, COSV53716648; called by muse, mutect2, varscan2
- NPM2 | c.387G>A p.E129= | Silent (SNP) | VAF 80/320 reads (25%) | called by muse, mutect2, varscan2
- NRK | c.2475G>A p.R825= | Silent (SNP) | VAF 114/209 reads (55%) | called by muse, mutect2, varscan2
- NRP1 | c.2577C>T p.I859= | Silent (SNP) | VAF 119/545 reads (22%) | called by muse, mutect2
- NUP205 | c.5985C>T p.F1995= | Silent (SNP) | VAF 421/591 reads (71%) | called by muse, mutect2, varscan2
- NUP210 | c.3276C>T p.I1092= | Silent (SNP) | VAF 113/416 reads (27%) | catalogued as rs752404764, COSV54403141; called by muse, mutect2, varscan2
- NUP98 | c.4128C>T p.T1376= (on ENST00000359171 / NM_001365126.1; = p.T1359= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 128/429 reads (30%) | catalogued as rs1283489600; called by muse, mutect2, varscan2
- OGDHL | c.1116G>A p.Q372= | Silent (SNP) | VAF 130/438 reads (30%) | called by muse, mutect2, varscan2
- OR10G9 | c.864C>T p.T288= | Silent (SNP) | VAF 77/258 reads (30%) | catalogued as rs1322546418, COSV66686012; called by muse, varscan2
- OR11H7 | c.564C>T p.S188= | Silent (SNP) | VAF 44/262 reads (17%) | called by muse, mutect2
- OR1C1 | c.90C>T p.L30= | Silent (SNP) | VAF 108/371 reads (29%) | catalogued as COSV68716138; called by muse, mutect2, varscan2
- OR1L3 | c.195C>T p.I65= | Silent (SNP) | VAF 123/309 reads (40%) | catalogued as rs770861361, COSV100506332, COSV59169448; called by muse, mutect2, varscan2
- OR2AG1 | c.99C>T p.I33= | Silent (SNP) | VAF 89/358 reads (25%) | catalogued as rs200103531, COSV56626741; called by muse, mutect2, varscan2
- OR4Q2 | c.186C>T p.F62= | Silent (SNP) | VAF 84/266 reads (32%) | called by muse, mutect2, varscan2
- OR52B2 | c.648C>T p.I216= | Silent (SNP) | VAF 135/421 reads (32%) | catalogued as rs1224930926, COSV73209368; called by muse, mutect2, varscan2
- OR56A5 | c.804G>A p.R268= | Silent (SNP) | VAF 158/513 reads (31%) | called by muse, mutect2, varscan2
- OR9H1P | c.414C>T p.V138= | Silent (SNP) | VAF 101/317 reads (32%) | called by muse, mutect2, varscan2
- PADI3 | c.717A>T p.V239= | Silent (SNP) | VAF 105/422 reads (25%) | catalogued as COSV64934680; called by muse, mutect2, varscan2
- PAPLN | c.297C>T p.F99= | Silent (SNP) | VAF 134/445 reads (30%) | catalogued as rs1274934549; called by muse, mutect2, varscan2
- PAPPA2 | c.4596G>A p.L1532= | Silent (SNP) | VAF 135/506 reads (27%) | called by muse, mutect2, varscan2
- PCDHA2 | c.1311C>T p.A437= | Silent (SNP) | VAF 212/455 reads (47%) | called by muse, mutect2, varscan2
- PCNT | c.9663G>A p.R3221= | Silent (SNP) | VAF 99/360 reads (28%) | called by muse, mutect2, varscan2
- PCNX2 | c.954C>T p.I318= | Silent (SNP) | VAF 116/490 reads (24%) | catalogued as rs370354806; called by muse, mutect2, varscan2
- PHF21A | c.1047C>T p.I349= (on ENST00000418153 / NM_001101802.3; = p.I350= on NM_016621.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 43/388 reads (11%) | called by muse, mutect2, varscan2
- PHKA2 | c.2502G>A p.V834= | Silent (SNP) | VAF 31/162 reads (19%) | called by muse, mutect2, varscan2
- PHLPP2 | c.2556C>T p.F852= | Silent (SNP) | VAF 74/278 reads (27%) | called by muse, mutect2, varscan2
- PKD1L3 | c.672C>T p.P224= | Silent (SNP) | VAF 119/407 reads (29%) | called by muse, mutect2, varscan2
- PKP4 | c.159A>G p.R53= | Silent (SNP) | VAF 77/313 reads (25%) | called by muse, mutect2, varscan2
- PLB1 | c.24C>T p.F8= | Silent (SNP) | VAF 88/346 reads (25%) | catalogued as rs1366886943, COSV59822884; called by muse, mutect2, varscan2
- PLCH2 | c.951C>T p.F317= | Silent (SNP) | VAF 130/521 reads (25%) | called by muse, mutect2, varscan2
- PLEC | c.5973C>T p.I1991= (on ENST00000322810 / NM_201380.4; = p.I1881= on NM_000445.5) | Silent (SNP) | VAF 162/612 reads (26%) | catalogued as rs782000075, COSV59638901; called by muse, mutect2
- PNLDC1 | c.1218A>G p.P406= | Silent (SNP) | VAF 105/321 reads (33%) | called by muse, mutect2, varscan2
- POLQ | c.7503C>T p.S2501= | Silent (SNP) | VAF 94/378 reads (25%) | called by muse, mutect2, varscan2
- PRAMEF20 | c.1329C>T p.A443= | Silent (SNP) | VAF 136/400 reads (34%) | called by muse, mutect2, varscan2
- PRKCZ | c.933C>T p.P311= | Silent (SNP) | VAF 69/279 reads (25%) | called by muse, mutect2, varscan2
- PRR32 | c.195G>A p.L65= | Silent (SNP) | VAF 137/267 reads (51%) | catalogued as rs1295629994; called by muse, mutect2, varscan2
- PSAP | c.660G>A p.Q220= | Silent (SNP) | VAF 115/486 reads (24%) | called by muse, mutect2, varscan2
- PSG2 | c.327C>T p.I109= | Silent (SNP) | VAF 97/482 reads (20%) | called by muse, mutect2, varscan2
- PSMD3 | c.1245C>T p.S415= | Silent (SNP) | VAF 79/302 reads (26%) | called by muse, mutect2, varscan2
- RER1 | c.33C>T p.V11= | Silent (SNP) | VAF 77/335 reads (23%) | catalogued as COSV60383697; called by muse, mutect2, varscan2
- RHBDF1 | c.1068C>T p.I356= | Silent (SNP) | VAF 186/730 reads (25%) | catalogued as rs768944027; called by muse, mutect2
- RIMS2 | c.429C>T p.I143= | Silent (SNP) | VAF 65/283 reads (23%) | called by muse, mutect2, varscan2
- RNGTT | c.405C>T p.F135= | Silent (SNP) | VAF 101/317 reads (32%) | called by muse, mutect2, varscan2
- ROS1 | c.2871G>A p.R957= | Silent (SNP) | VAF 122/429 reads (28%) | catalogued as rs191810593, COSV63856876; called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.15G>A p.K5= | Silent (SNP) | VAF 50/186 reads (27%) | called by muse, mutect2, varscan2
- RTN4R | c.843C>T p.S281= | Silent (SNP) | VAF 133/497 reads (27%) | catalogued as rs1478431874; called by muse, mutect2, varscan2
- RXFP2 | c.1422C>T p.F474= | Silent (SNP) | VAF 70/297 reads (24%) | catalogued as COSV53640978; called by muse, mutect2, varscan2
- SAMD9 | c.1923T>C p.L641= | Silent (SNP) | VAF 78/421 reads (19%) | called by muse, mutect2, varscan2
- SARS2 | c.48G>A p.R16= | Silent (SNP) | VAF 99/293 reads (34%) | catalogued as rs748402035; called by muse, mutect2, varscan2
- SEMA4D | c.633C>T p.F211= | Silent (SNP) | VAF 86/210 reads (41%) | catalogued as rs762081174, COSV59396522; called by muse, mutect2, varscan2
- SERPINB8 | c.1041C>T p.F347= | Silent (SNP) | VAF 110/420 reads (26%) | called by muse, varscan2
- SERPING1 | c.1257C>T p.F419= | Silent (SNP) | VAF 53/257 reads (21%) | catalogued as rs775042436, COSV53542067; called by muse, mutect2, varscan2
- SETD1A | c.1782C>T p.P594= | Silent (SNP) | VAF 130/429 reads (30%) | called by muse, mutect2, varscan2
- SIGLEC11 | c.981G>A p.G327= | Silent (SNP) | VAF 113/454 reads (25%) | called by muse, mutect2, varscan2
- SIPA1L2 | c.3150G>A p.E1050= | Silent (SNP) | VAF 22/468 reads (5%) | called by muse, mutect2
- SLC25A1 | c.847C>T p.L283= | Silent (SNP) | VAF 70/308 reads (23%) | catalogued as rs782037827; called by muse, mutect2, varscan2
- SLC25A39 | c.513C>T p.A171= (on ENST00000377095 / NM_001143780.3; = p.A163= on NM_016016.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/259 reads (27%) | catalogued as COSV56586599; called by muse, mutect2, varscan2
- SLC2A8 | c.444C>T p.I148= | Silent (SNP) | VAF 85/240 reads (35%) | catalogued as rs563205733; called by muse, mutect2, varscan2
- SLC34A2 | c.1185C>T p.V395= | Silent (SNP) | VAF 91/348 reads (26%) | catalogued as rs541971815, COSV65942181; called by muse, mutect2, varscan2
- SLC43A1 | c.141C>T p.S47= | Silent (SNP) | VAF 52/254 reads (20%) | called by muse, mutect2, varscan2
- SLC5A12 | c.117A>G p.R39= | Silent (SNP) | VAF 119/465 reads (26%) | called by muse, mutect2, varscan2
- SLC9A2 | c.711C>T p.I237= | Silent (SNP) | VAF 111/347 reads (32%) | called by muse, mutect2, varscan2
- SLITRK3 | c.1386C>T p.F462= | Silent (SNP) | VAF 108/459 reads (24%) | catalogued as COSV53847118; called by muse, mutect2, varscan2
- SMARCAL1 | c.1704C>T p.V568= | Silent (SNP) | VAF 79/295 reads (27%) | called by muse, mutect2, varscan2
- SMARCAL1 | c.1705C>T p.L569= | Silent (SNP) | VAF 78/291 reads (27%) | catalogued as rs764534644; called by muse, mutect2, varscan2
- SORCS3 | c.1566G>A p.R522= | Silent (SNP) | VAF 97/361 reads (27%) | called by muse, varscan2
- SORCS3 | c.2637C>T p.I879= | Silent (SNP) | VAF 119/437 reads (27%) | catalogued as COSV100863392; called by muse, mutect2, varscan2
- SP1 | c.1524T>C p.A508= (on ENST00000327443 / NM_138473.3; = p.A501= on NM_003109.1) | Silent (SNP) | VAF 145/425 reads (34%) | called by muse, mutect2, varscan2
- SPATA31A7 | c.1867C>T p.L623= | Silent (SNP) | VAF 117/809 reads (14%) | called by muse, mutect2, varscan2
- SPATA31D4 | c.2433G>A p.G811= | Silent (SNP) | VAF 114/296 reads (39%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.501A>G p.K167= | Silent (SNP) | VAF 119/284 reads (42%) | called by muse, mutect2, varscan2
- SVIL | c.321G>A p.R107= | Silent (SNP) | VAF 158/498 reads (32%) | catalogued as COSV63444871; called by muse, mutect2, varscan2
- TACC2 | c.2943G>A p.K981= | Silent (SNP) | VAF 125/393 reads (32%) | catalogued as rs1171043621; called by muse, mutect2, varscan2
- TAFA3 | c.243G>A p.R81= | Silent (SNP) | VAF 116/390 reads (30%) | called by muse, mutect2, varscan2
- TBCE | c.537C>T p.F179= (on ENST00000366601; = p.F242= on NM_003193.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 80/273 reads (29%) | called by muse, mutect2, varscan2
- TECTB | c.291C>T p.F97= | Silent (SNP) | VAF 86/288 reads (30%) | called by muse, mutect2, varscan2
- TENM1 | c.4320C>T p.F1440= | Silent (SNP) | VAF 142/242 reads (59%) | called by muse, mutect2, varscan2
- TGFB3 | c.183G>A p.V61= | Silent (SNP) | VAF 163/532 reads (31%) | called by muse, mutect2, varscan2
- TIE1 | c.1608C>T p.T536= | Silent (SNP) | VAF 118/435 reads (27%) | called by muse, mutect2, varscan2
- TM9SF2 | c.1155C>T p.F385= | Silent (SNP) | VAF 68/281 reads (24%) | catalogued as rs769080687; called by muse, mutect2, varscan2
- TNS1 | c.117C>T p.P39= | Silent (SNP) | VAF 72/332 reads (22%) | called by muse, mutect2, varscan2
- TRANK1 | c.2946C>T p.I982= | Silent (SNP) | VAF 151/491 reads (31%) | catalogued as rs1467549392; called by muse, mutect2, varscan2
- TRANK1 | c.2514G>A p.L838= | Silent (SNP) | VAF 98/401 reads (24%) | called by muse, mutect2, varscan2
- TRIM10 | c.438C>T p.I146= | Silent (SNP) | VAF 48/270 reads (18%) | called by muse, mutect2, varscan2
- TRIM29 | c.1048C>T p.L350= | Silent (SNP) | VAF 110/246 reads (45%) | called by muse, mutect2, varscan2
- TRIM58 | c.495G>A p.G165= | Silent (SNP) | VAF 78/301 reads (26%) | catalogued as COSV63570850; called by muse, mutect2, varscan2
- TRPC6 | c.1923C>T p.F641= | Silent (SNP) | VAF 239/567 reads (42%) | catalogued as rs1345322568; called by muse, mutect2, varscan2
- TRPM4 | c.3555C>T p.V1185= | Silent (SNP) | VAF 112/426 reads (26%) | called by muse, varscan2
- TRPM4 | c.3556C>T p.L1186= | Silent (SNP) | VAF 123/463 reads (27%) | catalogued as rs267605581; called by muse, mutect2, varscan2
- TSC22D1 | c.1341G>A p.V447= | Silent (SNP) | VAF 104/351 reads (30%) | called by muse, mutect2, varscan2
- TSKS | c.228C>T p.S76= | Silent (SNP) | VAF 25/509 reads (5%) | catalogued as rs749766557; called by muse, mutect2
- TTC34 | c.2271G>T p.G757= | Silent (SNP) | VAF 152/487 reads (31%) | called by muse, mutect2, varscan2
- TUBAL3 | c.744C>T p.S248= | Silent (SNP) | VAF 133/496 reads (27%) | catalogued as rs1265667943, COSV66814191; called by muse, mutect2, varscan2
- TXNDC16 | c.801C>T p.L267= | Silent (SNP) | VAF 73/317 reads (23%) | catalogued as COSV55987470, COSV99909362; called by muse, mutect2, varscan2
- USP28 | c.2706C>T p.L902= | Silent (SNP) | VAF 108/247 reads (44%) | called by muse, mutect2, varscan2
- UXS1 | c.297C>T p.F99= | Silent (SNP) | VAF 80/300 reads (27%) | catalogued as rs780126015, COSV51679458; called by muse, mutect2, varscan2
- WDR87 | c.6753G>A p.R2251= | Silent (SNP) | VAF 133/480 reads (28%) | called by muse, varscan2
- YY1AP1 | c.1764C>T p.I588= (on ENST00000295566 / NM_139118.2; = p.I531= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 130/485 reads (27%) | catalogued as rs768919392; called by muse, mutect2, varscan2
- ZFHX4 | c.9042G>A p.V3014= | Silent (SNP) | VAF 120/387 reads (31%) | catalogued as COSV50490894; called by muse, mutect2, varscan2
- ZNF284 | c.1296T>C p.C432= | Silent (SNP) | VAF 83/318 reads (26%) | catalogued as rs199693538; called by muse, mutect2, varscan2
- ZNF324 | c.816C>T p.L272= | Silent (SNP) | VAF 131/509 reads (26%) | called by muse, mutect2, varscan2
- ZNF521 | c.2034C>T p.S678= | Silent (SNP) | VAF 94/410 reads (23%) | catalogued as COSV64127962; called by muse, mutect2, varscan2
- ZNF549 | c.372G>A p.G124= (on ENST00000376233 / NM_001199295.2; = p.G111= on NM_153263.2) | Silent (SNP) | VAF 141/417 reads (34%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.213C>T p.P71= (on ENST00000252463; = p.P126= on NM_032805.3) | Silent (SNP) | VAF 30/500 reads (6%) | catalogued as rs1226468571; called by muse, mutect2
- ZSCAN18 | c.111C>T p.I37= | Silent (SNP) | VAF 137/443 reads (31%) | called by muse, mutect2, varscan2
- AC002519.1 | chr16:31793373 G>A | 3'Flank (SNP) | VAF 100/341 reads (29%) | called by muse, mutect2, varscan2
- BIRC8 | n.1076C>T | RNA (SNP) | VAF 66/295 reads (22%) | catalogued as rs761016305; called by muse, mutect2, varscan2
- C16orf95 | c.330+3808G>A | Intron (SNP) | VAF 104/370 reads (28%) | called by muse, mutect2, varscan2
- DAPK2 | c.858+1934G>A | Intron (SNP) | VAF 74/239 reads (31%) | called by muse, mutect2, varscan2
- DOK3 | chr5:177503231 C>T | 3'Flank (SNP) | VAF 163/348 reads (47%) | called by muse, mutect2, varscan2
- DUSP22 | c.508+63C>T | Intron (SNP) | VAF 78/561 reads (14%) | catalogued as COSV60523464; called by muse, mutect2
- GNGT1 | c.97-1283C>T | Intron (SNP) | VAF 89/475 reads (19%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-7711C>T | Intron (SNP) | VAF 93/328 reads (28%) | catalogued as rs752705004; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-7710C>T | Intron (SNP) | VAF 95/329 reads (29%) | catalogued as rs952648063; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+185C>T | Intron (SNP) | VAF 84/278 reads (30%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+8377C>T | Intron (SNP) | VAF 104/337 reads (31%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+22430C>T | Intron (SNP) | VAF 109/331 reads (33%) | catalogued as rs1363465865; called by muse, mutect2, varscan2
- MGAM | c.4619-7950C>T | Intron (SNP) | VAF 249/717 reads (35%) | called by muse, mutect2, varscan2
- NPAP1L | n.411C>T | RNA (SNP) | VAF 64/235 reads (27%) | called by muse, mutect2, varscan2
- SERPINA1 | c.1065+10C>T | Intron (SNP) | VAF 92/460 reads (20%) | catalogued as rs56388024, COSV63346158; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SUOX | c.*26C>T | 3'UTR (SNP) | VAF 118/464 reads (25%) | called by muse, mutect2, varscan2
- TIMM50 | chr19:39480748 G>A | 5'Flank (SNP) | VAF 189/599 reads (32%) | called by muse, mutect2, varscan2
- ZNF257 | c.227-435A>T | Intron (SNP) | VAF 68/256 reads (27%) | called by muse, mutect2, varscan2
- ZNF528 | c.272-875C>T | Intron (SNP) | VAF 82/300 reads (27%) | called by muse, mutect2, varscan2
